Somatic mutation profile of tumor specimen TCGA-DJ-A3V8-01A (aliquot TCGA-DJ-A3V8-01A-11D-A23M-08) from TCGA case TCGA-DJ-A3V8, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, columnar cell; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 28.5 years (10,398 days).
Specimen TCGA-DJ-A3V8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26705f5b-2f65-4ffd-a0ee-99fc8199c904.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A3V8-10A (Blood Derived Normal), aliquot TCGA-DJ-A3V8-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a91883c-8422-4868-9f20-fd221a538499

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 7, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- AOC1 | c.1339G>A p.G447S | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.755); catalogued as rs766216698, COSV100710907; called by mutect2, varscan2
- POM121L12 | c.504G>T p.E168D | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.148); catalogued as COSV101374958; called by muse, mutect2, varscan2
- RBM12B | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs774083454, COSV101197159; called by muse, mutect2, varscan2
- SDS | c.445G>A p.V149M | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as rs1236718928, COSV99981138; called by muse, mutect2, varscan2
- TGOLN2 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 48/642 reads (7%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.987); catalogued as rs775937805, COSV99965102; called by muse, mutect2
- TYRO3 | c.1504G>A p.D502N | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs142874537; called by muse, mutect2
- DNAH7 | c.5796A>G p.K1932= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV100416664; called by muse, mutect2, varscan2
- SUV39H2 | c.147G>A p.V49= | Silent (SNP) | VAF 34/117 reads (29%) | catalogued as COSV100543157; called by muse, mutect2, varscan2
- ZCCHC14 | c.1248C>G p.S416= (on ENST00000268616; = p.S553= on NM_015144.3) | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99234355; called by muse, mutect2
